Somatic mutation profile of tumor specimen TCGA-WC-A884-01A (aliquot TCGA-WC-A884-01A-11D-A39W-08) from TCGA case TCGA-WC-A884, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 35.2 years (12,840 days).
Specimen TCGA-WC-A884-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af92afaf-ad4b-4bd2-a895-a4e5f2a9f9ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A884-10A (Blood Derived Normal), aliquot TCGA-WC-A884-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e1338d9-c6f8-451a-99f4-5ba620174527

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 37/74 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63309305, COSV63309328; called by muse, mutect2, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BEST3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as rs117505973; called by muse, mutect2, varscan2
- CUX2 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200707164, COSV55652824; called by muse, mutect2, varscan2
- FAM47A | c.1819A>G p.K607E | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV60495284; called by muse, mutect2, varscan2
- PTCH2 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs777545138; called by muse, mutect2, varscan2
- LONRF3 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2
- RPL36AL | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2, varscan2
